Somatic mutation profile of tumor specimen C3L-00610-01 (aliquot CPT0025110009) from CPTAC case C3L-00610, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.2 years (20,900 days).
Specimen C3L-00610-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2adf3644-194b-4c08-aac8-c64d8bcb0bda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00610-31 (Blood Derived Normal), aliquot CPT0029410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd09f85b-ccb2-4718-b92d-cbc97522b43f

The open-access MAF lists 50 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, 3'UTR 4, Frame Shift Del 3, Intron 3, Splice Site 1, 5'UTR 1, In Frame Ins 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.262T>C p.W88R | Missense Mutation (SNP) | VAF 97/237 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1553619431, CM031392, CM951278, COSV56542744, COSV56546104, COSV56548816; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS14 | c.452A>G p.E151G | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs749142773; called by muse, mutect2, varscan2
- BAG2 | c.511A>C p.K171Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs116163209; called by muse, mutect2, varscan2
- CXXC1 | c.350A>T p.D117V | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99497008; called by muse, mutect2, varscan2
- GLCE | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.083); catalogued as COSV55944905; called by muse, mutect2, varscan2
- ITIH6 | c.2012C>A p.S671Y | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99513653; called by muse, mutect2, varscan2
- KIF20A | c.2239G>C p.E747Q | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV67509812; called by muse, mutect2, varscan2
- LDB1 | c.896G>A p.R299Q (on ENST00000425280 / NM_001321612.2; = p.R263Q on NM_003893.5) | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs990101456, COSV63288589, COSV63289656; called by muse, mutect2, varscan2
- NET1 | c.929T>C p.I310T (on ENST00000355029 / NM_001047160.3; = p.I256T on NM_005863.5) | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs753890242; called by muse, mutect2, varscan2
- WDFY3 | c.4552T>G p.S1518A | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV99881748; called by muse, mutect2, varscan2
- ZNF43 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.071); catalogued as COSV61683180; called by muse, mutect2, varscan2
- ACAP3 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- ACSL5 | c.1573G>C p.D525H (on ENST00000354273; = p.D581H on NM_016234.3) | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CILP | c.3396C>G p.Y1132* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- COPG1 | c.2159-1G>A p.X720_splice | Splice Site (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- GPR37 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2
- GRB10 | c.882A>T p.Q294H (on ENST00000398812; = p.Q236H on NM_001001550.3) | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- MAN1C1 | c.413del p.G138Afs*44 | Frame Shift Del (DEL) | VAF 20/168 reads (12%) | called by mutect2, pindel, varscan2
- NEK1 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PBRM1 | c.2737_2738del p.E913Nfs*5 | Frame Shift Del (DEL) | VAF 40/125 reads (32%) | called by mutect2, pindel, varscan2
- PCED1B | c.242A>T p.E81V | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2
- PHOX2B | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PVALB | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PYCR2 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RSRC2 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SCAF11 | c.2393C>A p.S798Y | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SRP68 | c.1673T>G p.F558C | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, varscan2
- SYDE1 | c.2083del p.V695Sfs*17 | Frame Shift Del (DEL) | VAF 53/266 reads (20%) | called by mutect2, pindel, varscan2
- TRDV2 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC6 | c.278G>C p.G93A (on ENST00000267368; = p.G1362A on NM_001310135.3) | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.267); called by muse, mutect2
- TTC6 | c.280C>T p.P94S (on ENST00000267368; = p.P1363S on NM_001310135.3) | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- URGCP | c.2577C>G p.F859L (on ENST00000453200 / NM_001077663.3; = p.F850L on NM_017920.4) | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDBF2 | c.4261G>T p.V1421L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF367 | c.863_864insCCCCAG p.T288_L289insPS | In Frame Ins (INS) | VAF 26/111 reads (23%) | called by mutect2, pindel, varscan2
- ABL1 | c.1944C>T p.F648= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, varscan2
- DTNA | c.1116A>G p.E372= | Silent (SNP) | VAF 96/391 reads (25%) | called by muse, mutect2, varscan2
- FAM214B | c.246C>T p.G82= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- KNL1 | c.1728C>T p.S576= (on ENST00000346991 / NM_170589.5; = p.S550= on NM_144508.5) | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- MARVELD3 | c.717G>A p.Q239= | Silent (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- UBQLN2 | c.1569C>T p.A523= | Silent (SNP) | VAF 71/226 reads (31%) | catalogued as rs762076931; called by muse, mutect2, varscan2
- ZNF555 | c.402G>A p.K134= | Silent (SNP) | VAF 43/165 reads (26%) | called by muse, mutect2, varscan2
- ADHFE1 | c.888-329A>G | Intron (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- ARL4C | c.*176G>A | 3'UTR (SNP) | VAF 66/282 reads (23%) | catalogued as rs1293632115; called by muse, varscan2
- CYP2A7P2 | n.403C>T | RNA (SNP) | VAF 39/183 reads (21%) | called by muse, mutect2, varscan2
- GH1 | c.11-13G>T | Intron (SNP) | VAF 86/319 reads (27%) | called by muse, mutect2, varscan2
- LDHA | c.245-39T>C | Intron (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- NAAA | c.-6C>G | 5'UTR (SNP) | VAF 18/86 reads (21%) | catalogued as rs1023615633; called by muse, varscan2
- PNPLA3 | c.*333del | 3'UTR (DEL) | VAF 38/162 reads (23%) | called by mutect2, pindel, varscan2
- RAB11FIP5 | c.*26G>T | 3'UTR (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- TMEM79 | c.*52A>C | 3'UTR (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2
